Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A239, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A239-01A (Primary Tumor).

[page 1 of 4]
Date Re-reviewed	3/30/11	

Print this Page

Specimen Description

Surgical Pathology Report

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

*****Clinical History*****

Patient History: R thyroid nodule.

ICD-O-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw 4/8/11

*****Final Pathologic Diagnosis*****

- A. Thyroid, excision:
- Papillary thyroid carcinoma (see attached synoptic report).
- Lymph node negative for metastatic carcinoma (0/1).
- B. Left mid jugular chain lymph node, excision:
- Lymph node negative for metastatic carcinoma (0/1).

Electronically Signed By
[REDACTED]
[REDACTED]

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:
Specimen type: Thyroid gland.
Tumor location: Right lobe.
Tumor size: 4.5 x 2.5 x 2.7 cm.
Histologic type: Papillary thyroid carcinoma.
Tumor grade: Low grade.
Lymphatic/vascular invasion: Yes.
Capsular invasion: No.
Tumor extent:
Confined to the thyroid: Yes.
Multifocal: No.
Invasion of thyroid cartilage or hyoid bone: No.
Infiltration of adjacent structures: No.
Margins:
For partial or subtotal resection: Negative.
Lymph nodes:
Total number examined: 2
Number positive: 0

[page 2 of 4]
Sex:M

Specimen Description

Surgical Pathology Report

*****Clinical History*****

Patient History: R thyroid nodule.

*****Final Pathologic Diagnosis*****

A. Thyroid, excision:

- Papillary thyroid carcinoma (see attached synoptic report).
- Lymph node negative for metastatic carcinoma (0/1).

B. Left mid jugular chain lymph node, excision:

- Lymph node negative for metastatic carcinoma (0/1).

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: Thyroid gland.

Tumor location: Right lobe.

Tumor size: 4.5 x 2.5 x 2.7 cm.

Histologic type: Papillary thyroid carcinoma.

Tumor grade: Low grade.

Lymphatic/vascular invasion: Yes.

Capsular invasion: No.

Tumor extent:

Confined to the thyroid: Yes.

Multifocal: No.

Invasion of thyroid cartilage or hyoid bone: No.

Infiltration of adjacent structures: No.

Margins:

For partial or subtotal resection: Negative.

[page 3 of 4]
Lymph nodes:

Total number examined: 2
Number positive: 0
Number negative: 2
Extranodal extension: N/A
pTNM: pT3N0Mx

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

AF1. Total thyroid: (FROZEN SECTION PERFORMED)

- Thyroid neoplasm, favor papillary thyroid carcinoma.

[REDACTED]

BF1. Left mid jugular chain lymph node: (FROZEN SECTION PERFORMED)

- Benign.

[REDACTED]

[REDACTED]

*****SPECIMEN(S) RECEIVED:*****

A: Thyroid, REG

B: Lymph node, ENT, REG

*****GROSS DESCRIPTION:*****

The specimens are received in two properly labeled containers with the patient's name and accession number, two frozen sections are performed.

A. The specimen is designated "total thyroid" and consists of a 51.4 gram total thyroidectomy specimen, with the right lobe measuring 5.5 x 4.5 x 3.5 cm, and the left lobe measuring 4.0 x 2.0 x 1.0 cm. The external surface is smooth and tan-brown. The specimen is inked as follows: right lobe-black, left lobe-blue, isthmus-yellow. Sectioning reveals an ill-defined, indurated, tan-yellow, lobulated mass which abuts the capsule, located in the right lobe, 4.5 x 2.5 x 2.7 cm. The mass is located 1.0 cm from the isthmus. The remaining thyroid parenchyma is red-brown and meaty. Sectioning of the isthmus and left lobe reveals unremarkable parenchyma. The mass does not appear to invade the capsule. (P) RS 12

Summary of Cassettes: AF1, frozen section, resubmitted as received; A1-4, sections of tumor to capsule; A5-6, sections of tumor to adjacent normal parenchyma; A7-8, random sections of right lobe; A9-10, random sections of left lobe; A11, entire isthmus

[page 4 of 4]
B. The specimen is designated "left mid jugular chain LN" and consists of a 2.2 x 0.5 cm cylindrically-shaped lymph node, entirely submitted for frozen section, resubmitted as received in cassette BF1.

Top of

Source: NCI Genomic Data Commons file f0f7c3ca-7320-4612-bfe0-0ca426360e78 (TCGA-FE-A239.E0EADBBD-4454-4BF8-A0FF-3E08C3634324.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).